Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A5XL, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A5XL-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

Diagnosis:

Adrenal, left, laparoscopic adrenalectomy

- Pheochromocytoma, 109 g
- Surgical margins free of pheochromocytoma.
- The tumor is circumscribed and encapsulated, without lymphovascular space invasion identified.

ICD-O-3

Pheochromocytoma NOS
8700/0

Clinical History:

-year-old male with a pheochromocytoma.

Site: Adrenal Gland NOS
C74.9

JW 4/3/13

Gross Description:

Received is one appropriately labeled container, additionally labeled "left adrenal gland." It holds an intact 109.1 gram, 7.2 x 6.0 x 5.0 cm unoriented tissue fragment with a focally cauterized surface with fibrofatty adhesions. The specimen is inked green and sectioned to demonstrate a variegated orange/yellow to tan/brown cut surface. The periphery is a well circumscribed yellow/tan thick capsule. No residual adrenal gland or cortex is appreciated. Representative sections are submitted in blocks A1-A10. Digital photographs have been taken.

Malignancy behavior not obvious.
BCR

Reviewed (initials)	2/19/13	

Source: NCI Genomic Data Commons file b0797949-b993-4fce-8311-d277143a92d3 (TCGA-QT-A5XL.B53FEDEC-A419-4394-A982-93E75FD10DE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).